Gene-level copy-number profile of tumor specimen MP2PRT-PAVNLG-TMP1-A from MP2PRT case MP2PRT-PAVNLG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,419 days).
Specimen MP2PRT-PAVNLG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 498dc056-0fd0-44ae-82cc-651328e919d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVNLG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/e7025ad6-771a-4f09-ba51-34c6872c6a11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 566; copy number 1: 5,612; copy number 2: 50,908; copy number 3: 273; copy number 4: 1,538.

Homozygous deletions (total copy number 0; autosomes only): 513 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–827,796, 47 genes (within-gene range 0–1): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2.
- chr2:38,814–342,118, 9 genes: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865.
- chr3:11,745–409,417, 7 genes (within-gene range 0–1): LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr7:158,856,558–159,233,377, 5 genes: DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:144,930,358–145,066,685, 8 genes: ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:12,134–215,893, 12 genes (within-gene range 0–1): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1.
- chr9:36,893,462–36,893,531, 1 gene (within-gene range 0–2): MIR4476.
- chr10:133,623,895–133,778,699, 20 genes: FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr11:134,712,539–135,075,908, 6 genes: LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr12:12,310–277,123, 14 genes: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4.
- chr12:132,822,187–132,956,304, 1 gene (within-gene range 0–1): CHFR.
- chr12:132,835,374–133,238,549, 25 genes (within-gene range 0–1): RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr13:114,234,887–114,337,626, 7 genes: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:105,672,308–106,879,812, 176 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:101,751,032–101,979,093, 19 genes: DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:11,555–138,677, 14 genes: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr18:80,147,924–80,247,514, 4 genes: PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:186,373–1,605,473, 98 genes (broad region; genes not listed).
- chr19:58,428,632–58,605,223, 23 genes: AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:46,598,604–46,691,226, 4 genes: S100B, PRMT2, DSTNP1, RPL23AP4.
- chr22:50,600,793–50,801,309, 11 genes (within-gene range 0–1): MAPK8IP2, ARSA, Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,809. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
